Somatic mutation profile of tumor specimen MBCProject_0065_T1_WES (aliquot MBCProject_0065_T1_WES_1) from CMI case MBCProject_0065, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 40.7 years (14,860 days).
Specimen MBCProject_0065_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 09b1042e-ef68-4da1-846b-359257daf7aa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0065_SALIVA (Saliva), aliquot MBCProject_0065_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f7247aa0-7a24-4b63-b430-15c279fdebf7

The open-access MAF lists 29 somatic variants for this specimen: 21 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 6, Splice Region 3, Intron 2, Nonsense Mutation 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 89/344 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AKAP8 | c.1013G>T p.R338L | Missense Mutation (SNP) | VAF 19/154 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.629); catalogued as rs560438541, COSV54100834; called by muse, mutect2, varscan2
- CXADR | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 26/174 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.101); catalogued as rs755566570; called by muse, mutect2, varscan2
- FLNC | c.3722G>A p.R1241H | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.051); catalogued as rs370520806; called by muse, mutect2
- MAGI2 | c.3706+4C>T | Splice Region (SNP) | VAF 5/65 reads (8%) | catalogued as rs1290658478, COSV62700478; called by muse, mutect2
- MOGAT1 | c.729G>T p.W243C | Missense Mutation (SNP) | VAF 27/193 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.127); catalogued as COSV71479848; called by muse, mutect2, varscan2
- PAM | c.2444G>A p.R815Q | Missense Mutation (SNP) | VAF 17/222 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs759560994; called by muse, mutect2
- SCN9A | c.5021G>A p.G1674E (on ENST00000303354; = p.G1663E on NM_002977.3) | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57602644; called by muse, mutect2, varscan2
- TOR1AIP1 | c.475+5G>A | Splice Region (SNP) | VAF 24/244 reads (10%) | catalogued as rs560675641; called by muse, mutect2
- AC006059.2 | c.1915C>T p.Q639* | Nonsense Mutation (SNP) | VAF 10/63 reads (16%) | called by muse, mutect2, varscan2
- AMIGO3 | c.973C>G p.R325G | Missense Mutation (SNP) | VAF 37/235 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- CLSTN3 | c.2369C>G p.S790C | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- DUSP4 | c.204_221del p.C69_R74del | In Frame Del (DEL) | VAF 26/222 reads (12%) | called by mutect2, pindel
- FMN2 | c.2088G>C p.Q696H | Missense Mutation (SNP) | VAF 11/160 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.071); called by muse, mutect2
- GDI2 | c.680C>A p.P227Q | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MRPS26 | c.473T>A p.L158Q | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- P2RY13 | c.655A>C p.T219P | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.808); called by muse, mutect2
- PTPN18 | c.530A>G p.K177R | Missense Mutation (SNP) | VAF 10/163 reads (6%) | SIFT tolerated (0.58); PolyPhen benign (0.001); called by muse, mutect2
- TEX11 | c.644C>T p.P215L (on ENST00000344304; = p.P200L on NM_031276.3) | Missense Mutation (SNP) | VAF 7/116 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2
- WTAP | c.453C>T p.S151= | Splice Region (SNP) | VAF 27/241 reads (11%) | called by muse, mutect2, varscan2
- XPR1 | c.1242C>G p.I414M | Missense Mutation (SNP) | VAF 57/635 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.314); called by muse, mutect2
- H2BC17 | c.330C>T p.H110= | Silent (SNP) | VAF 37/355 reads (10%) | catalogued as rs769896157; called by muse, mutect2
- ILDR1 | c.1272C>T p.V424= (on ENST00000344209 / NM_001199799.2; = p.V380= on NM_175924.4) | Silent (SNP) | VAF 21/204 reads (10%) | called by muse, mutect2
- MCTP1 | c.1806C>T p.D602= | Silent (SNP) | VAF 7/40 reads (18%) | called by muse, mutect2
- NANS | c.852G>A p.E284= | Silent (SNP) | VAF 14/125 reads (11%) | called by muse, mutect2, varscan2
- NEDD9 | c.795A>G p.P265= | Silent (SNP) | VAF 11/120 reads (9%) | called by muse, mutect2, varscan2
- STXBP5L | c.1302C>G p.V434= | Silent (SNP) | VAF 7/132 reads (5%) | called by muse, mutect2
- LMO3 | c.206+6406T>C | Intron (SNP) | VAF 21/86 reads (24%) | catalogued as rs1487968233; called by muse, mutect2, varscan2
- RELN | c.10281-35T>C | Intron (SNP) | VAF 33/115 reads (29%) | called by muse, mutect2, varscan2
